BEATAML1.0 case 2256 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/4a62467f-6537-4358-8b63-07c7b4f59d73

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Acute myelomonocytic leukemia: ICD-O-3 morphology code: 9867/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.6 years (21,028 days); Progression or recurrence: no; ELN risk classification: Intermediate.

Biospecimens (2 samples)
- Sample BA2060D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
- Sample BA2741D: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
